Somatic mutation profile of tumor specimen ALCH-B2PC-TTP1-A (aliquot ALCH-B2PC-TTP1-A-1-0-D-A777-36) from ALCHEMIST case ALCH-B2PC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.1 years (24,859 days).
Specimen ALCH-B2PC-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e183d1f-b235-4dbd-89ff-3fb4b208edb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2PC-NB1-A (Blood Derived Normal), aliquot ALCH-B2PC-NB1-A-1-0-D-A777-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d886199e-a547-4975-b22c-90717428eb01

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Intron 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TRIM51 | c.1145G>A p.C382Y | Missense Mutation (SNP) | VAF 20/830 reads (2%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99792643; called by muse, mutect2
- TTBK1 | c.1316del p.P439Qfs*16 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | catalogued as COSV104389590; called by pindel, varscan2
- ADCY10 | c.3887C>G p.A1296G | Missense Mutation (SNP) | VAF 28/605 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.058); called by muse, mutect2
- DONSON | c.181G>C p.A61P | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.899); called by muse, varscan2
- EML1 | c.388A>T p.I130F | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2
- MMP2 | c.629A>G p.D210G | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- SIX3 | c.829C>A p.P277T | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- TRIM13 | c.439C>G p.Q147E | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.444); called by muse, mutect2
- ZC3H4 | c.2885T>C p.I962T | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- ZNF674 | c.1056C>A p.H352Q | Missense Mutation (SNP) | VAF 24/757 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2
- ZNF827 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 13/186 reads (7%) | called by muse, mutect2
- ERBB2 | c.2430C>G p.V810= | Silent (SNP) | VAF 13/184 reads (7%) | called by muse, mutect2
- GFPT2 | c.1398C>T p.N466= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as rs1335278161, COSV99517153; called by mutect2, varscan2
- NALCN | c.2706C>T p.S902= | Silent (SNP) | VAF 15/259 reads (6%) | called by muse, mutect2
- GPX3 | c.87+144G>C | Intron (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- MCUR1 | c.536-1733T>C | Intron (SNP) | VAF 3/29 reads (10%) | catalogued as rs1390610824; called by muse, mutect2
